Somatic mutation profile of tumor specimen TARGET-10-PARPXV-09A (aliquot TARGET-10-PARPXV-09A-01D) from TARGET case TARGET-10-PARPXV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,600 days).
Specimen TARGET-10-PARPXV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee5d64ac-05b4-4b18-9d59-32501deb49b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPXV-10A (Blood Derived Normal), aliquot TARGET-10-PARPXV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcf73b52-6508-479b-ab0b-85e1df14ac95

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 5'Flank 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.4053G>C p.M1351I | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53240162, COSV53257873; called by muse, mutect2
- CCDC168 | c.12284C>T p.S4095F | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV59419782; called by muse, mutect2, varscan2
- DNAH6 | c.6711G>A p.M2237I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1374669184; called by muse, mutect2, varscan2
- FAM71E2 | c.1342C>A p.P448T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV52772544; called by muse, mutect2, varscan2
- NBAS | c.5556G>C p.Q1852H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV99871903; called by muse, mutect2, varscan2
- UMODL1 | c.2024G>A p.R675Q (on ENST00000408910 / NM_001004416.2; = p.R803Q on NM_173568.3) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs981528998, COSV61160981; called by muse, mutect2
- DVL2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.346_347insCAAGACCGA p.V116delinsARPM | In Frame Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- VAMP7 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.098); called by muse, mutect2
- ADGRL4 | c.1518A>T p.A506= | Silent (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1488G>A p.Q496= | Silent (SNP) | VAF 9/9 reads (100%) | called by muse, mutect2, varscan2
- GALNT8 | c.1155C>T p.N385= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs370114403; called by muse, varscan2
- AC018563.1 | n.679G>T | RNA (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2
- LIPT1 | chr2:99154898 C>T | 5'Flank (SNP) | VAF 4/11 reads (36%) | catalogued as rs1014920111; called by muse, mutect2
